TCGA case TCGA-G3-A25X — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08428220-abd4-484e-85ca-3673454c837e

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 73.9 years (26,988 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,779 days (4.9 years); Child pugh classification: A; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,359 days (3.7 years); Disease response: Tumor Free.
- Days to follow up: 1,779 days (4.9 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Albumin 0.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 0.3; Blood test normal range upper: 0.5].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.1].
- Alpha Fetoprotein 11 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 10].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.4; Blood test normal range upper: 1.4].
- Total Bilirubin 1.1 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.4].
- Platelets 102 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 165 cm; BMI: 23.9.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G3-A25X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-G3-A25X-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G3-A25X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G3-A25X-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-G3-A25X-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; Hepatic inflammation adj tissue: Mild.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,779 days; disease-specific survival: no event (censored), 1,779 days; disease-free interval: no event (censored), 1,779 days; progression-free interval: no event (censored), 1,779 days.
